CPTAC case C3L-08267 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/74efa0d9-d95e-4192-804e-cbbc3ad6f362

Demographics
Sex at birth: male; Race: white; Year of birth: 1947; Vital status: Alive; Country of birth: Serbia.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Age at diagnosis: 74.9 years (27,372 days); Year of diagnosis: 2022; AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N3b; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Residual disease: R0; Days to last known disease status: 1,035 days (2.8 years); Progression or recurrence: no; Days to last follow up: 1,035 days (2.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 22; Lymph nodes tested: 29.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Days to treatment start: 83 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Days to treatment start: 83 days; Days to treatment end: 405 days (1.1 years); Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 384 days (1.1 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 652 days (1.8 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-08267-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Cardia; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 1 day; Initial weight: 816 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-08267-21: Section location: Cardia; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3L-08267-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 1 day; Method of sample procurement: Blood Draw.
